Somatic mutation profile of tumor specimen TCGA-EE-A2MN-06A (aliquot TCGA-EE-A2MN-06A-11D-A197-08) from TCGA case TCGA-EE-A2MN, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 59.9 years (21,885 days).
Specimen TCGA-EE-A2MN-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2e1aa28-d939-423b-b3e5-298b3889d910.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2MN-10A (Blood Derived Normal), aliquot TCGA-EE-A2MN-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02240a6d-b9d1-497e-b2e0-68cdecb82b99

The open-access MAF lists 186 somatic variants for this specimen: 118 protein-altering or splice-affecting, 61 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 61, Nonsense Mutation 7, RNA 3, Intron 2, In Frame Del 1, 3'UTR 1, Frame Shift Ins 1, Splice Region 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDOB | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 32/73 reads (44%) | catalogued as rs1172384674, COSV66397420; ClinVar: likely pathogenic; called by muse, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 47/132 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- AC005833.1 | c.1217C>T p.T406I | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious, low confidence (0.01); catalogued as COSV52899095; called by muse, mutect2, varscan2
- AC242842.3 | c.320C>T p.T107I | Missense Mutation (SNP) | VAF 92/412 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1378600297; called by muse, mutect2, varscan2
- ACADL | c.928A>G p.T310A | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV52054312; called by muse, mutect2, varscan2
- ADAMTS6 | c.3205G>A p.E1069K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.156); catalogued as COSV58684085; called by muse, mutect2, varscan2
- ADAMTSL4 | c.242G>A p.S81N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.038); catalogued as COSV55002988; called by muse, mutect2, varscan2
- ADCY1 | c.1020+1G>A p.X340_splice | Splice Site (SNP) | VAF 8/26 reads (31%) | catalogued as COSV52038124; called by muse, varscan2
- AFAP1 | c.1580G>A p.G527E | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.426); catalogued as COSV61796941; called by muse, mutect2, varscan2
- AFF4 | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.98); PolyPhen benign (0.005); catalogued as rs867632138, COSV54796756; called by muse, mutect2, varscan2
- AGPAT2 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 153/420 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV58246991; called by muse, mutect2, varscan2
- ALX4 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.2); catalogued as rs757361317, COSV100240999; called by muse, mutect2, varscan2
- ARHGAP44 | c.1928C>T p.T643I | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as rs553386211, COSV52396736; called by muse, mutect2, varscan2
- ARMCX1 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 62/74 reads (84%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV65705347; called by muse, mutect2, varscan2
- ATM | c.7297C>T p.Q2433* | Nonsense Mutation (SNP) | VAF 8/11 reads (73%) | catalogued as COSV53756517; called by muse, mutect2, varscan2
- ATP8A2 | c.3335G>A p.R1112Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.79); PolyPhen benign (0.135); catalogued as rs768704138, COSV54963252; called by muse, mutect2, varscan2
- BANK1 | c.2101T>A p.F701I | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59846131; called by muse, mutect2, varscan2
- BAZ2B | c.1979A>G p.D660G | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV58604979; called by muse, mutect2, varscan2
- BOC | c.3119C>T p.P1040L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.073); catalogued as COSV56354392; called by muse, mutect2, varscan2
- BTBD9 | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 28/111 reads (25%) | catalogued as rs764393519, COSV58430829; called by muse, mutect2, varscan2
- C2orf16 | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as COSV101284382; called by muse, mutect2, varscan2
- C2orf16 | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.052); catalogued as COSV101284383; called by muse, mutect2, varscan2
- C3orf20 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV53786935; called by muse, mutect2, varscan2
- CAMSAP1 | c.2053C>T p.L685F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.074); catalogued as rs1181153066, COSV100409764; called by muse, mutect2, varscan2
- CBL | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.018); catalogued as COSV50646395; called by muse, mutect2, varscan2
- CD163L1 | c.2408C>T p.P803L | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as COSV58019764; called by muse, mutect2, varscan2
- CDH26 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54849981; called by muse, mutect2, varscan2
- CNBD1 | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV101582222, COSV73074098; called by muse, mutect2
- COBL | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as COSV54350895; called by muse, mutect2, varscan2
- COL19A1 | c.1861G>A p.G621S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1473690837, COSV59578670; called by muse, mutect2, varscan2
- COL5A3 | c.4318C>T p.P1440S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV53414313; called by muse, mutect2, varscan2
- COL7A1 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV60398164; called by muse, mutect2
- CRISP3 | c.799G>A p.A267T (on ENST00000371159 / NM_001368123.1; = p.A249T on NM_006061.4) | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs1253132642, COSV53821730; called by muse, mutect2, varscan2
- CXCL14 | c.328G>A p.E110K (on ENST00000337225; = p.E98K on NM_004887.5) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs774689516, COSV61499340; called by muse, varscan2
- CYP27C1 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as rs767621928, COSV58867349; called by muse, mutect2, varscan2
- DNAH5 | c.10306C>T p.R3436C | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs774231638, COSV54237891; called by muse, mutect2, varscan2
- DYNAP | c.332T>G p.M111R (on ENST00000321600; = p.M85R on NM_173629.3) | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV58666620; called by muse, mutect2, varscan2
- ERBB4 | c.2807G>A p.G936E | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as rs762743981, COSV61478163; called by muse, mutect2, varscan2
- EVPL | c.4141G>A p.D1381N | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV56913215; called by muse, mutect2, varscan2
- EXD1 | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV59255153; called by muse, mutect2, varscan2
- FHDC1 | c.2426C>T p.S809F | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV52601328; called by muse, mutect2, varscan2
- FNDC4 | c.101T>C p.L34P | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53022142; called by muse, mutect2, varscan2
- FRMPD2 | c.1229G>A p.W410* | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | catalogued as COSV59720268; called by muse, varscan2
- FSIP1 | c.1262C>T p.S421F | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV63225675; called by muse, mutect2
- GLDN | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV59089783; called by muse, mutect2, varscan2
- GPLD1 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as COSV57759170; called by muse, mutect2, varscan2
- GPR19 | c.464T>C p.V155A | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV60124056; called by muse, mutect2, varscan2
- GRID2 | c.2093C>T p.P698L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56181872; called by muse, varscan2
- HECTD4 | c.10504G>A p.V3502I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs759373433, COSV66395203; called by mutect2, varscan2
- HMMR | c.2116A>G p.K706E | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV62374966; called by muse, mutect2, varscan2
- IGLV8-61 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs542479842, COSV66502625; called by muse, varscan2
- IL22RA1 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54629361; called by muse, mutect2, varscan2
- IRF2BP2 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV64015315; called by muse, mutect2, varscan2
- ITGAD | c.1797G>A p.M599I | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs778676347, COSV66756947; called by muse, mutect2, varscan2
- JAKMIP3 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.83); PolyPhen benign (0.391); catalogued as rs542645419, COSV53825836; called by muse, mutect2, varscan2
- JMJD6 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV57973911; called by muse, mutect2, varscan2
- KIFC3 | c.2444C>T p.P815L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV101109161, COSV65551519; called by muse, mutect2, varscan2
- LELP1 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV64202603; called by muse, mutect2, varscan2
- MCMBP | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63509825; called by muse, mutect2, varscan2
- MUC5B | c.4999G>A p.G1667S | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as COSV71596494; called by muse, mutect2, varscan2
- MYO5A | c.3284T>C p.L1095P | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV62562301; called by muse, mutect2, varscan2
- MYO6 | c.900C>T p.Y300= | Splice Region (SNP) | VAF 30/74 reads (41%) | catalogued as rs768772589, COSV64119981; called by muse, mutect2, varscan2
- NAA15 | c.1112C>G p.T371S | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.913); catalogued as COSV56720996; called by muse, mutect2, varscan2
- NEB | c.6853G>A p.D2285N | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV51427433; called by muse, mutect2, varscan2
- NFYA | c.167A>T p.Q56L | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as COSV58199184; called by muse, mutect2, varscan2
- NID1 | c.3010A>G p.R1004G | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV51623862, COSV51624120; called by muse, mutect2, varscan2
- NR2C1 | c.1422A>C p.L474F | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.224); catalogued as COSV58010773; called by muse, mutect2, varscan2
- NRP1 | c.1961G>A p.W654* | Nonsense Mutation (SNP) | VAF 111/296 reads (38%) | catalogued as COSV55171285; called by muse, mutect2, varscan2
- OLFML2B | c.1765G>A p.D589N | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs769211874, COSV54194890; called by muse, mutect2, varscan2
- OR10H4 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs199816165, COSV59061504; called by muse, mutect2, varscan2
- OR4C6 | c.903G>A p.M301I | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs868308791, COSV58602653; called by muse, mutect2, varscan2
- PCDHA7 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as rs782007391, COSV65338596; called by muse, mutect2, varscan2
- PCDHA8 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as COSV65325085; called by muse, mutect2, varscan2
- PCDHB1 | c.1311G>A p.M437I | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV60631948; called by muse, mutect2, varscan2
- PCDHB4 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.081); catalogued as rs782620651, COSV52021200; called by muse, mutect2, varscan2
- PCSK5 | c.368C>G p.S123C | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV65092304; called by muse, mutect2, varscan2
- PIWIL1 | c.2521C>T p.L841F | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); catalogued as COSV55348954; called by muse, mutect2, varscan2
- PKHD1L1 | c.4642A>G p.T1548A | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV65747259; called by muse, mutect2, varscan2
- PKP4 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as rs144253065; called by muse, mutect2, varscan2
- PLAG1 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 68/250 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.544); catalogued as COSV57613189; called by muse, mutect2, varscan2
- PLCB4 | c.2627G>A p.G876E | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.996); catalogued as rs866533934, COSV53796419; called by muse, mutect2, varscan2
- PLXNB1 | c.2431C>T p.H811Y | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV56491800; called by mutect2, varscan2
- PNPLA7 | c.3351T>A p.Y1117* | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | catalogued as COSV53002053; called by muse, mutect2, varscan2
- PRB4 | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 74/411 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.455); catalogued as rs1487997477, COSV54398276; called by muse, varscan2
- PSD4 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV55528079; called by muse, mutect2, varscan2
- PTCD2 | c.290C>T p.T97I | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.103); catalogued as rs1466179940, COSV57338496; called by muse, mutect2, varscan2
- QRICH2 | c.3074C>T p.P1025L | Missense Mutation (SNP) | VAF 83/192 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53155097; called by muse, mutect2, varscan2
- RIPPLY3 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV61566593; called by muse, mutect2, varscan2
- RP1L1 | c.5338G>A p.E1780K | Missense Mutation (SNP) | VAF 77/137 reads (56%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV66757436; called by muse, mutect2, varscan2
- RSBN1L | c.2230C>T p.H744Y | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.253); catalogued as COSV58509482; called by muse, mutect2, varscan2
- RYR3 | c.7118G>A p.G2373D (on ENST00000389232; = p.G2374D on NM_001036.6) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV66799592; called by muse, mutect2, varscan2
- SACS | c.10723C>T p.H3575Y | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV66543470; called by muse, mutect2, varscan2
- SCLT1 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.461); catalogued as COSV99827900; called by muse, mutect2, varscan2
- SCLT1 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as rs749094740, COSV99827902; called by muse, mutect2, varscan2
- SCN11A | c.4366C>T p.P1456S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs1423082221, COSV56565185; called by muse, mutect2, varscan2
- SETD2 | c.6748C>T p.Q2250* | Nonsense Mutation (SNP) | VAF 27/57 reads (47%) | catalogued as COSV57443390; called by muse, mutect2, varscan2
- SIPA1L1 | c.257G>A p.R86K | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT tolerated (0.81); PolyPhen benign (0.028); catalogued as COSV62171691; called by muse, mutect2, varscan2
- SLF2 | c.2803C>T p.R935C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as rs367702979, COSV53276268; called by muse, mutect2, varscan2
- SLIT2 | c.2165C>T p.S722F | Missense Mutation (SNP) | VAF 69/188 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs763417377, COSV56570312; called by muse, mutect2, varscan2
- SORCS1 | c.1667A>G p.N556S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.161); catalogued as rs868280396, COSV53884413; called by muse, mutect2, varscan2
- SPOCD1 | c.3113C>T p.S1038F | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57097831; called by muse, mutect2, varscan2
- SPOCK3 | c.1186C>T p.H396Y | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.197); catalogued as COSV62730565; called by muse, mutect2, varscan2
- SSX2 | c.477G>C p.R159S (on ENST00000337502 / NM_175698.2; = p.G208A on NM_003147.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs1233390386; called by mutect2, varscan2
- ST8SIA4 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 24/59 reads (41%) | PolyPhen probably damaging (1); catalogued as COSV51512909; called by muse, mutect2, varscan2
- SUPT5H | c.2213C>T p.S738F | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV63240823; called by muse, mutect2, varscan2
- THSD7B | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.674); catalogued as COSV55657721; called by muse, mutect2, varscan2
- TMIGD2 | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs757060511, COSV56666891, COSV56667797; called by muse, mutect2, varscan2
- TTN | c.40975G>A p.E13659K (on ENST00000591111; = p.E6235K on NM_003319.4) | Missense Mutation (SNP) | VAF 27/49 reads (55%) | PolyPhen probably damaging (0.994); catalogued as COSV60180655; called by muse, mutect2, varscan2
- TTN | c.36929G>A p.G12310E (on ENST00000591111; = p.G4886E on NM_003319.4) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | PolyPhen probably damaging (0.959); catalogued as rs55723264, COSV59979154; called by muse, mutect2, varscan2
- TXNIP | c.1164_1166del p.N389del | In Frame Del (DEL) | VAF 20/46 reads (43%) | catalogued as rs1553765789; called by pindel, varscan2
- UGT2A3 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV52361063; called by muse, mutect2, varscan2
- VCPKMT | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); catalogued as rs757113813, COSV67776228; called by mutect2, varscan2
- WWOX | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.73); catalogued as COSV68359974; called by muse, mutect2, varscan2
- ZBP1 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1053041220, COSV59063001; called by muse, mutect2, varscan2
- ZNF534 | c.913C>T p.H305Y (on ENST00000332323 / NM_001143939.3; = p.H292Y on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as rs267605633, COSV56514865; called by muse, mutect2, varscan2
- ZNF681 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1037392108, COSV68073537; called by muse, mutect2, varscan2
- KIR3DL2 | c.221G>C p.R74T | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC29A1 | c.749dup p.L250Ffs*5 | Frame Shift Ins (INS) | VAF 36/194 reads (19%) | called by pindel, varscan2
- AC242842.3 | c.321C>T p.T107= | Silent (SNP) | VAF 91/411 reads (22%) | called by muse, mutect2, varscan2
- ADAMTSL3 | c.4317C>T p.T1439= | Silent (SNP) | VAF 54/166 reads (33%) | catalogued as rs766761265, COSV54457224, COSV99721145; called by muse, mutect2, varscan2
- ADGRF1 | c.933C>T p.F311= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as rs1383579171, COSV51946481; called by muse, mutect2, varscan2
- ALX4 | c.1014C>T p.P338= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV100240864, COSV100241001; called by muse, mutect2, varscan2
- ANKS4B | c.405G>A p.L135= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs752698422, COSV61139639; called by muse, mutect2, varscan2
- ASPHD2 | c.402C>T p.A134= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV53219757; called by muse, mutect2, varscan2
- CAMSAP1 | c.2052C>T p.A684= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100409765; called by muse, mutect2, varscan2
- CD300E | c.405G>A p.R135= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs1478309767, COSV60791049; called by muse, mutect2, varscan2
- CFAP54 | c.5994C>T p.V1998= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV61573269; called by muse, mutect2, varscan2
- CLEC6A | c.348G>C p.V116= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV65987757; called by muse, mutect2, varscan2
- CORO2B | c.964C>T p.L322= | Silent (SNP) | VAF 31/57 reads (54%) | catalogued as COSV55954932; called by muse, mutect2, varscan2
- CRB1 | c.1479C>T p.F493= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as rs770919155, COSV66329493; ClinVar: benign; called by muse, mutect2, varscan2
- CSMD2 | c.9681C>T p.S3227= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs372068474, COSV99587365; called by muse, mutect2, varscan2
- DNAH7 | c.11121C>T p.I3707= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV56773904; called by muse, mutect2, varscan2
- ELAVL2 | c.339C>T p.S113= | Silent (SNP) | VAF 27/42 reads (64%) | catalogued as COSV56365554; called by muse, mutect2, varscan2
- EPHA3 | c.2295C>T p.F765= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs773426684, COSV60694998; called by muse, mutect2, varscan2
- EPHX1 | c.1344C>T p.F448= | Silent (SNP) | VAF 43/62 reads (69%) | catalogued as COSV55302219, COSV99689178; called by muse, mutect2, varscan2
- FAM81B | c.744C>T p.F248= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as rs751751535, COSV51980508; called by muse, mutect2, varscan2
- GAB3 | c.1632C>T p.A544= | Silent (SNP) | VAF 114/150 reads (76%) | catalogued as COSV65820162; called by muse, mutect2, varscan2
- GBP5 | c.609C>T p.S203= | Silent (SNP) | VAF 50/161 reads (31%) | catalogued as COSV58593453; called by muse, mutect2, varscan2
- GDPD4 | c.120C>T p.I40= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV60020733; called by muse, mutect2, varscan2
- GLT1D1 | c.981G>A p.Q327= (on ENST00000442111 / NM_001366889.1; = p.Q247= on NM_144669.3) | Silent (SNP) | VAF 55/149 reads (37%) | catalogued as COSV55884285; called by muse, mutect2, varscan2
- GZF1 | c.606G>A p.K202= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as rs748679363, COSV57636943; called by muse, mutect2, varscan2
- ITGA8 | c.396C>T p.S132= | Silent (SNP) | VAF 37/118 reads (31%) | catalogued as COSV65231801; called by muse, mutect2, varscan2
- KATNB1 | c.1056G>A p.Q352= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV65551508; called by muse, mutect2, varscan2
- KATNB1 | c.1830G>A p.E610= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as rs1366069564, COSV65551512; called by muse, mutect2, varscan2
- KIAA1217 | c.900C>A p.P300= | Silent (SNP) | VAF 47/100 reads (47%) | catalogued as COSV100287527, COSV56816225, COSV56819361; called by muse, mutect2, varscan2
- KRT15 | c.720G>A p.L240= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as rs200579517, COSV54180536; called by muse, mutect2, varscan2
- LAMB3 | c.1965C>T p.I655= | Silent (SNP) | VAF 32/134 reads (24%) | catalogued as COSV61918032; called by muse, mutect2, varscan2
- LPAR1 | c.888C>T p.F296= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as COSV62687549; called by muse, mutect2, varscan2
- LRIG1 | c.1974C>T p.F658= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs1360824743, COSV56243795; called by muse, mutect2, varscan2
- MAGEB6 | c.123C>T p.S41= | Silent (SNP) | VAF 25/27 reads (93%) | catalogued as rs774839904, COSV66872596; called by muse, mutect2, varscan2
- MAST4 | c.3639C>T p.L1213= (on ENST00000403625 / NM_001164664.2; = p.L1024= on NM_015183.3) | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1254320348, COSV55132219; called by muse, mutect2
- MUC16 | c.24900C>T p.L8300= | Silent (SNP) | VAF 36/69 reads (52%) | catalogued as rs1432092441, COSV67478396; called by muse, mutect2, varscan2
- MYH11 | c.5145G>A p.E1715= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as COSV55560398; called by muse, mutect2, varscan2
- NUDT17 | c.606A>G p.Q202= | Silent (SNP) | VAF 36/133 reads (27%) | catalogued as COSV57907855; called by muse, mutect2, varscan2
- OAZ2 | c.207C>T p.L69= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV58107176; called by muse, mutect2, varscan2
- OR13C4 | c.378C>T p.I126= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as COSV52926828, COSV52927580; called by muse, mutect2, varscan2
- OR5H6 | c.6C>T p.F2= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV67351789; called by muse, mutect2, varscan2
- PCDH17 | c.120G>A p.R40= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV64974268; called by muse, mutect2, varscan2
- PCDHA9 | c.1614C>T p.R538= | Silent (SNP) | VAF 46/148 reads (31%) | catalogued as COSV65329199; called by muse, mutect2, varscan2
- POGK | c.1806C>G p.T602= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV100902549, COSV63311927; called by muse, mutect2, varscan2
- PRKAA2 | c.150G>A p.Q50= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as COSV64804867; called by muse, mutect2, varscan2
- PRR16 | c.882G>A p.T294= (on ENST00000407149 / NM_001300783.2; = p.T271= on NM_016644.2) | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as rs199619912, COSV65394504; called by muse, mutect2, varscan2
- PTCHD1 | c.1854G>A p.L618= | Silent (SNP) | VAF 41/58 reads (71%) | catalogued as rs985359622, COSV65061691; called by muse, mutect2, varscan2
- PURA | c.135C>T p.G45= | Silent (SNP) | VAF 5/11 reads (45%) | called by mutect2, varscan2
- RBM34 | c.906C>T p.A302= | Silent (SNP) | VAF 71/121 reads (59%) | catalogued as COSV64013018; called by muse, mutect2, varscan2
- SH3BP4 | c.558C>T p.P186= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV60644787; called by muse, varscan2
- SH3RF2 | c.1347C>T p.S449= | Silent (SNP) | VAF 126/310 reads (41%) | catalogued as COSV63040055; called by muse, mutect2, varscan2
- SLC15A2 | c.2073C>T p.I691= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as COSV55199125; called by muse, mutect2, varscan2
- SLC5A4 | c.1125C>T p.P375= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV56671988; called by muse, mutect2, varscan2
- SPEN | c.10758G>A p.E3586= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV65270685, COSV65271032; called by muse, mutect2, varscan2
- STEAP3 | c.447C>T p.I149= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as COSV61529822; called by muse, mutect2, varscan2
- TAS2R5 | c.612C>T p.V204= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as COSV56095201; called by muse, mutect2, varscan2
- TBC1D12 | c.1080C>A p.S360= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs1443976785, COSV56555752; called by muse, mutect2, varscan2
- TMEM196 | c.297C>T p.S99= | Silent (SNP) | VAF 19/124 reads (15%) | catalogued as COSV68255534; called by muse, mutect2, varscan2
- TRIML1 | c.897C>T p.L299= | Silent (SNP) | VAF 66/181 reads (36%) | catalogued as rs201972598, COSV60193494, COSV60195535; called by muse, mutect2, varscan2
- TTBK1 | c.1356G>A p.R452= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV52493792; called by muse, mutect2, varscan2
- UBR1 | c.5001C>T p.F1667= | Silent (SNP) | VAF 43/132 reads (33%) | catalogued as rs200935129, COSV51932838; called by muse, mutect2, varscan2
- UGT2B17 | c.688C>T p.L230= | Silent (SNP) | VAF 73/174 reads (42%) | catalogued as COSV58502132; called by muse, mutect2, varscan2
- ZNF217 | c.1329C>T p.D443= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as rs754309091, COSV56594045; called by muse, mutect2, varscan2
- DCHS2 | n.6737C>T | RNA (SNP) | VAF 23/80 reads (29%) | catalogued as COSV61775304; called by muse, mutect2, varscan2
- ECM2 | chr9:92494127 C>T | 3'Flank (SNP) | VAF 21/62 reads (34%) | catalogued as COSV100755910, COSV60741870; called by muse, mutect2, varscan2
- LST1 | c.*43C>T | 3'UTR (SNP) | VAF 8/37 reads (22%) | catalogued as rs751756670, COSV53001796; called by muse, mutect2, varscan2
- MIR548I2 | n.132C>T | RNA (SNP) | VAF 56/168 reads (33%) | catalogued as rs568510694; called by muse, mutect2, varscan2
- NACA | c.71-3858C>T | Intron (SNP) | VAF 13/40 reads (33%) | catalogued as COSV63271555; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.400+6864C>T | Intron (SNP) | VAF 65/149 reads (44%) | catalogued as COSV57125889; called by muse, mutect2, varscan2
- UBTFL2 | n.869G>A | RNA (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
